Somatic mutation profile of cancer-model specimen HCM-CSHL-0860-C18-85M (3D Organoid, passage 4; aliquot HCM-CSHL-0860-C18-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0860-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 70.3 years (25,687 days).
Specimen HCM-CSHL-0860-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33e155f5-9dc5-46e1-8dfd-1f53478040ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0860-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0860-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9113652-bfd8-4326-84f5-a35f30ce093a

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Nonsense Mutation 5, 5'Flank 1, Nonstop Mutation 1, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 107/277 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ACKR4 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs746421374; called by muse, mutect2, varscan2
- AFF3 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs868486028, COSV57866119; called by muse, mutect2, varscan2
- AGAP3 | c.1855C>T p.R619* (on ENST00000622464; = p.R655* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/518 reads (3%) | catalogued as rs1265218429; called by muse, mutect2
- ARHGEF37 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 166/479 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as rs528783472; called by muse, varscan2
- COL25A1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 269/519 reads (52%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1233681099, COSV101211297; called by muse, varscan2
- DSCAML1 | c.4070G>T p.G1357V (on ENST00000321322; = p.G1297V on NM_020693.4) | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV100355025; called by muse, varscan2
- DSCAML1 | c.4069G>T p.G1357C (on ENST00000321322; = p.G1297C on NM_020693.4) | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751431959; called by muse, varscan2
- GABPB1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 17/432 reads (4%) | catalogued as COSV99590247; called by muse, mutect2
- HECTD2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs201433936; called by muse, mutect2, varscan2
- HS3ST2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 172/358 reads (48%) | catalogued as rs1319192100, COSV54462447; called by muse, varscan2
- IKZF2 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1375506817; called by muse, mutect2, varscan2
- MARF1 | c.2074T>G p.S692A | Missense Mutation (SNP) | VAF 16/599 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1236116531; called by muse, mutect2
- MRPS35 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 33/469 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs772505121; called by muse, mutect2
- MUC5B | c.3431C>A p.S1144Y | Missense Mutation (SNP) | VAF 234/454 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs2672801; called by muse, mutect2, varscan2
- NOTCH1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 146/298 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs756642176, COSV53041965; ClinVar: uncertain significance; called by muse, varscan2
- PLCXD2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201796337; called by muse, mutect2
- PTPRU | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV60533802; called by muse, mutect2
- RIMBP2 | c.453+1G>A p.X151_splice | Splice Site (SNP) | VAF 110/235 reads (47%) | catalogued as rs1451846888; called by muse, mutect2, varscan2
- SBNO2 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 46/854 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199715870; called by muse, mutect2
- SCAF8 | c.1499T>G p.F500C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65794050; called by muse, mutect2
- SNAP25 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs374115269; called by muse, mutect2, varscan2
- TBC1D25 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs782002768; called by muse, mutect2, varscan2
- TEK | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760084463; called by muse, mutect2, varscan2
- ABCA13 | c.11477C>A p.S3826* | Nonsense Mutation (SNP) | VAF 70/240 reads (29%) | called by muse, varscan2
- ABCB1 | c.3072A>T p.E1024D | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ASMTL | c.212A>T p.N71I | Missense Mutation (SNP) | VAF 138/456 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.222); called by muse, varscan2
- ASXL1 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CEP120 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- CTR9 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAH11 | c.5653C>A p.L1885I | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- DOP1A | c.3506C>A p.A1169E | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ELAPOR2 | c.3036A>T p.K1012N (on ENST00000450689 / NM_001142749.3; = p.K845N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM200B | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FCRL4 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- JPH2 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 134/944 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- KIAA1549 | c.2340G>T p.L780F | Missense Mutation (SNP) | VAF 43/791 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.114); called by muse, mutect2
- LTBP3 | c.3752G>A p.R1251H (on ENST00000301873 / NM_001130144.3; = p.R1204H on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTERF1 | c.653dup p.L218Ffs*12 | Frame Shift Ins (INS) | VAF 77/559 reads (14%) | called by mutect2, pindel, varscan2
- MUC16 | c.29627C>G p.T9876S | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NAGK | c.77T>G p.I26S | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NFE2L1 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- NPR3 | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- NR3C1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 30/508 reads (6%) | called by muse, mutect2
- OR5D13 | c.178A>C p.I60L | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- PCDHB4 | c.2388A>C p.*796Yext*7 | Nonstop Mutation (SNP) | VAF 11/249 reads (4%) | called by muse, mutect2
- PDE2A | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SDS | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 14/528 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2
- SRP68 | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD15 | c.4711T>A p.S1571T | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TMTC1 | c.2349G>C p.K783N (on ENST00000539277 / NM_001193451.2; = p.K675N on NM_175861.3) | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2
- VPS13A | c.9322G>A p.E3108K | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZSCAN12 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 17/470 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.029); called by muse, mutect2
- ABCD1 | c.1680G>A p.P560= | Silent (SNP) | VAF 191/466 reads (41%) | catalogued as rs782005164, COSV99497643; called by muse, mutect2, varscan2
- AGMAT | c.105G>A p.Q35= | Silent (SNP) | VAF 66/922 reads (7%) | catalogued as rs762705531; called by muse, mutect2
- AVPR1A | c.15C>T p.A5= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as rs768185467; called by muse, mutect2
- BMPER | c.75C>T p.V25= | Silent (SNP) | VAF 17/612 reads (3%) | called by muse, mutect2
- CCT7 | c.426C>G p.T142= | Silent (SNP) | VAF 24/320 reads (8%) | catalogued as rs199840482, COSV57821536; called by muse, mutect2
- CFAP46 | c.4896G>C p.L1632= | Silent (SNP) | VAF 13/307 reads (4%) | called by muse, mutect2
- COL1A2 | c.2310C>A p.P770= | Silent (SNP) | VAF 67/408 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.2139C>T p.N713= (on ENST00000297405 / NM_001363185.1; = p.N609= on NM_052900.3) | Silent (SNP) | VAF 82/164 reads (50%) | catalogued as COSV52099863; called by muse, mutect2, varscan2
- DPP6 | c.1266C>T p.H422= (on ENST00000377770 / NM_001364500.2; = p.H360= on NM_001936.5) | Silent (SNP) | VAF 67/452 reads (15%) | catalogued as rs377039321, COSV100126832; called by muse, mutect2, varscan2
- DZIP1 | c.1339T>C p.L447= | Silent (SNP) | VAF 15/514 reads (3%) | called by muse, mutect2
- NPSR1 | c.1056G>A p.T352= | Silent (SNP) | VAF 65/254 reads (26%) | catalogued as rs143448171; called by muse, mutect2, varscan2
- PCNX2 | c.6405C>T p.D2135= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as rs764436742, COSV50781545; called by muse, mutect2, varscan2
- PGAP1 | c.2598T>A p.L866= | Silent (SNP) | VAF 84/172 reads (49%) | called by muse, varscan2
- PHIP | c.2034C>T p.T678= | Silent (SNP) | VAF 74/177 reads (42%) | called by muse, mutect2, varscan2
- RGS22 | c.192G>A p.L64= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as COSV100693761; called by muse, varscan2
- RNMT | c.366C>T p.G122= | Silent (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- STX1B | c.855G>A p.T285= | Silent (SNP) | VAF 36/437 reads (8%) | catalogued as rs762220243; ClinVar: likely benign; called by muse, mutect2
- ZNF26 | c.918A>G p.R306= | Silent (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- ZNF512B | c.1728C>T p.G576= | Silent (SNP) | VAF 125/1217 reads (10%) | catalogued as rs765552673; called by muse, mutect2, varscan2
- KRBA1 | c.-56C>T | 5'UTR (SNP) | VAF 56/493 reads (11%) | catalogued as rs1036588361, COSV99753160; called by muse, mutect2, varscan2
- LINC00662 | n.633T>G | RNA (SNP) | VAF 148/525 reads (28%) | called by muse, mutect2, varscan2
- ZBTB7B | chr1:155010995 G>A | 5'Flank (SNP) | VAF 30/430 reads (7%) | called by muse, mutect2
- ZFX | c.58+805_58+816del | Intron (DEL) | VAF 92/194 reads (47%) | called by mutect2, pindel, varscan2
